Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5SH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5SH-06A (Metastatic).

ICD O-3

Melanoma, malignant
8/20/13

Site Lymph Node NOS
C77.9

2/18/13

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Lymph node

Tumor size: 3 x 3 x 3 cm

Tumor features: None specified

Satellite nodules: Not specified

Histologic type: Metastatic neoplasm, malignant melanoma

Histologic grade:

Lymph nodes: 1/1 positive for metastasis (Unspecified 1/1)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

IHPA Discrepancy		✓
Reviewed Initials	Kml	

Source: NCI Genomic Data Commons file b5bbdc05-4799-4092-9fd0-744bc3464bd8 (TCGA-EB-A5SH.147D1052-01D6-4FA0-B757-D9AD0C32C00A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).